Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KB, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KB-01A (Primary Tumor).

[page 1 of 2]
printed

UUID: C9A25B61-433D-47D7-9F2C-820205292D13 TCGA-VD-A8KB-01A-PR Redacted		Page 1 of 2
		REPORT Tel:
Forename 	Sex 	Clinical Consultant & Location
Unit No 	This Copy For:	

SPECIMEN

Transcleral resected melanoma - right eye and subretinal fluid

CLINICAL DETAILS

Known choroidal naevus right eye.
Reviewed at yearly for
Discharged from
Complains of blurred vision since
Referred to here by optician.

ICD-O-3
Melanoma, epithelioid & spindle cell
mixed 8776/3
Site @ Choroid C69.3
9/11/14

MACROSCOPIC DESCRIPTION

A local resection specimen measuring 16 x 15 x 12mm consisting of a black pigmented tumour and a thin layer of sclera. In a separate syringe there is 0.1ml of blood coloured subretinal fluid. Frozen for research.

MICROSCOPY

Histological sections demonstrate a local resection specimen of a choroidal melanoma with attached adjacent normal choroid and sclera.

The tumour is partially pigmented and consists predominantly of spindle cells but with small foci of epithelioid cells. The epithelioid component represents approx. 15% of the total tumour cell population. The melanoma cells are positive for MelanA, HSP-27 (score 2) and partially positive for CD10.

The number of mitoses is moderately high, approx. 7/40 high power fields. The microvasculature of the melanoma is prominent, but closed loops are not present in the tissue planes evaluated. "Vascular seas" can also be observed: there is, however, no obvious tumour infiltration. The lymphocytic infiltrate within tumour is minimal.

There is tumour extension into the sclera and close to the scleral resection margin at the base of the tumour. The lateral resection margins are free of tumour.

Reported:

Pathologist:

Electronically Verified:

[page 2 of 2]
Department of Pathology

Page 2 of 2

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

DIAGNOSIS

Trans-scleral resection of a choroidal melanoma of mixed cell type.

COMMENT

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. Should the DNA concentration be insufficient for MLPA, microsatellite analysis will be undertaken.

A supplementary report will follow as soon as these investigations are complete.

SUPPLEMENTARY REPORT

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED] which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report.

In summary, sequence analysis demonstrated: normal chromosome 1, essentially normal chromosome 3, gains in chromosome 6p and borderline gains in chromosome 8q.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

Reported:

Pathologist:

Electronically Verified:

Criteria	11/6/13	Yes	No
MLPA Discrepancy			✓
Du-/Synchronous Primary History			✓

Source: NCI Genomic Data Commons file 7da3452e-6409-430e-a058-c130e0966d80 (TCGA-VD-A8KB.C9A25B61-433D-47D7-9F2C-820205292D13.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).